CCDI case PBBHMD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3c7339bb-ec13-4123-b371-cd3c4a94162d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,214 days).

Biospecimens (4 samples)
- Sample 0D8ODE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0D8ODL, 0D8ODM (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D8PJV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
